Surgical pathology report (de-identified scan), TCGA case TCGA-ZS-A9CG, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Tayside Tissue Bank, specimen TCGA-ZS-A9CG-01A (Primary Tumor).

[page 1 of 4]
Nature of Specimen(s)

1. Extended right hepatectomy for presumed primary hepatocellular carcinoma
2. Gallbladder

Clinical Information Supplied

MALE.

Large ?primary liver tumour. Recent sigmoid colectomy for carcinoma. Per TSS, the path on the sigmoid colectomy showed no malignancy.

PROUREMENT DATE

Macro Report

BCK

Liver Resection Dataset

Gross description

Type of specimen: Non-anatomic (wedge) resection
Site/Segment of origin: Right
Specimen dimension: 200 x 180 x 110mm
Number of tumours present: 1
Maximum tumour diameter: 85mm
Satellite tumour present: No
Distance from nearest hepatic resection margin: 12mm
Macroscopic involvement of vessels: No
Liver capsule intact and smooth: No, see comment
Invasion of adherent or adjacent organ: No
Lymph nodes received: No

ICD.O 3

Page 1 of 4

Carcinoma, hepatocellular NOS 8170/3

Site: Liver C22.D
JAS 5/19/14

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR

[page 2 of 4]
Comments and block codes

Received is a portion of liver measuring 200x180x up to 110mm. Slicing reveals a tumour closely abutting the serosal surface that measures approximately 85x70x60mm. The serosal surface is puckered but there is no evidence of macroscopic invasion through the liver capsule. The cut surface of the tumour is cream with a green tinge and appears to have a fibrous capsule. The capsule is puckered but there is no evidence of macroscopic invasion through the liver capsule. Throughout the rest of the liver there are multiple distended vessels within portal tracts that appear to be filled with cream-coloured tissue similar to that of the tumour. The tumour lies 12mm away from the resection margin which is inked blue. The background liver does not appear obviously cirrhotic. Within the background liver a single other cream coloured nodule is noted that does not seem to be associated with a portal area that measures 4mm in maximum dimension.

Blocks taken: 1A-1H representative sections through the tumour; 1I section of other nodule noted; 1J-1L representative sections through the dilated vessels in the background liver; 1M normal background liver.

2. A gallbladder containing bile with no obvious focal lesions identified.

Histology

Tumour type: Hepatocellular carcinoma NOS

Tumour grade/differentiation
by worse area: Moderate

Tumour cells present at margin: No

If margin is clear: is clearance >10mm: Yes

Macroscopic vascular invasion
confirmed: No

Page 2 of 4

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR

[page 3 of 4]
Microscopic vascular invasion
identified:

Yes

Evidence of response to
preoperative treatment:

N/A

Background liver
Fibrosis:

None present

Aetiology:

Not known, see comment

Comments

A single tumour is surrounded by a fibrous capsule and consists of sheets of hepatocytes with loss of the normal liver architecture. There is evidence of cytological atypia and nuclear pleomorphism. In some areas of the tumour there is formation of variably sized gland like structures. Outwith the tumour multiple foci of lymphovascular invasion are identified. There is no significant bile production by the tumour. The features are those of a hepatocellular carcinoma.

Within the surrounding normal liver there is evidence of chronic inflammation and regenerative liver nodules. Within the portal areas through the rest of the liver there is evidence of portal vein distention. The portal vein branches are completely full of a foreign body giant cell reaction to embolic material.

There is no evidence of fibrosis within the background liver. There is some mild steatosis and mild chronic inflammation within the portal areas. A Perl's stain for iron does reveal scattered iron deposition within hepatocytes. There is no evidence of any obvious underlying pathology to suggest the aetiology of this hepatocellular carcinoma. However, the presence of iron within hepatocytes does raise the possibility of a iron storage disorder and clinical correlation is advised.

Pathological staging:

pT2, pNx, pMx

2. Sections show a heavily autolysed gallbladder but with no evidence of malignancy.

Page 3 of 4

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR

[page 4 of 4]
Signature of Pathologist(s)

Page 4 of 4

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR

Source: NCI Genomic Data Commons file 7eb685d7-a2ef-42dd-8d30-675b1e819935 (TCGA-ZS-A9CG.8A0E7BA8-7262-4832-89DA-61893BE4B458.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).